Somatic mutation profile of tumor specimen 0DHHLB from CCDI case PBBUMY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,793 days).
Specimen 0DHHLB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 750a76d0-7d52-49a1-9908-128d78db4bdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHHJ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee2b2acd-91ef-4f4e-91a0-63b2b56d2f50

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1, Splice Site 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534120185; called by muse, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 29/286 reads (10%) | catalogued as COSV59989381; called by muse, varscan2
- OR2L13 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs768923821, COSV63548490, COSV63562975; called by muse, varscan2
- PPIB | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs200786931; called by muse, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 27/267 reads (10%) | called by muse, varscan2
- RCAN1 | c.253-1711C>T | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, varscan2
- TECRL | c.-82C>A | 5'UTR (SNP) | VAF 28/51 reads (55%) | catalogued as COSV101169158; called by muse, varscan2
